Somatic mutation profile of tumor specimen MP2PRT-PARTBD-TMP1-A (aliquot MP2PRT-PARTBD-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PARTBD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,348 days).
Specimen MP2PRT-PARTBD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89ed2e10-abfb-4dd7-9684-632dec0f0ab7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARTBD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARTBD-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9a95ffa-e64e-4549-aa60-c5a1272e014b

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBLN2 | c.3208C>T p.R1070C | Missense Mutation (SNP) | VAF 157/403 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243966226; called by muse, mutect2, varscan2
- STAB2 | c.5350G>A p.D1784N | Missense Mutation (SNP) | VAF 195/552 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs147807697, COSV66335384; called by muse, mutect2, varscan2
- UGGT2 | c.3047G>A p.R1016H | Missense Mutation (SNP) | VAF 100/283 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs778022471, COSV65076801; called by muse, mutect2, varscan2
- OBSL1 | c.5146G>A p.E1716K | Missense Mutation (SNP) | VAF 17/565 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- OR2B3 | c.571G>C p.D191H | Missense Mutation (SNP) | VAF 120/600 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PAFAH2 | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 28/520 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCN10A | c.839A>T p.D280V | Missense Mutation (SNP) | VAF 69/231 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SDK1 | c.2576C>A p.A859E | Missense Mutation (SNP) | VAF 86/343 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- SLC6A1 | c.751C>A p.L251M | Missense Mutation (SNP) | VAF 104/395 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SYNCRIP | c.215G>C p.G72A | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- SRCIN1 | c.402C>T p.S134= | Silent (SNP) | VAF 60/662 reads (9%) | catalogued as rs1210248430; called by muse, mutect2
